TCGA case TCGA-80-5607 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Ontario Institute for Cancer Research (OICR)/Ottawa. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/645903b5-ba37-48a1-985b-a019b8db3236

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the colon (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Progression or recurrence: Yes; Timepoint: Post Initial Treatment.
- ECOG performance status: 1.
- Disease response: With Tumor; Timepoint: Follow-up.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 15; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 1985.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-80-5607-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-80-5607-01A-02-BS2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 20.
- Sample TCGA-80-5607-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-80-5607-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung.
- Follow-up form: New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Colon.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy colon cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), time not recorded; disease-specific survival: no event (censored), time not recorded; progression-free interval: no event (censored), time not recorded.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-80-5607-01A-31D-1943-01): tumor purity 0.49, ploidy 2.02, whole-genome doublings 0.
